Somatic mutation profile of tumor specimen 0DEAG1 from CCDI case PBBPEI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.5 years (1,652 days).
Specimen 0DEAG1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3533820d-0d1a-4417-ad2a-70157ff45e9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEAG0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c9a8f32-fd09-4416-808f-82d38b33697b

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, In Frame Del 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL662899.2 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 158/221 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101021668; called by muse, mutect2, varscan2
- CACNA1G | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 179/476 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV61727104; called by muse, mutect2, varscan2
- CCR7 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 121/303 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs575312747; called by muse, mutect2, varscan2
- KCNN4 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 104/247 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775470701, COSV53456821; called by muse, mutect2, varscan2
- NMD3 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 90/1219 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63619029; called by muse, mutect2
- NPR2 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 246/544 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs771997028; called by muse, mutect2, varscan2
- OPRM1 | c.409T>C p.F137L | Missense Mutation (SNP) | VAF 318/387 reads (82%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs1210840287; called by muse, mutect2, varscan2
- TLR10 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 336/844 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs200661388; called by muse, mutect2, varscan2
- UROC1 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 275/573 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.159); catalogued as rs527715107; called by muse, mutect2, varscan2
- VIPR1 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 84/852 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs375928724, COSV57297900; called by muse, mutect2
- CTNNB1 | c.102_113del p.I35_G38del | In Frame Del (DEL) | VAF 210/574 reads (37%) | called by mutect2, varscan2
- EEA1 | c.3605del p.K1202Rfs*6 | Frame Shift Del (DEL) | VAF 514/1219 reads (42%) | called by mutect2, varscan2
- ELF1 | c.224A>C p.D75A | Missense Mutation (SNP) | VAF 20/687 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.13); called by muse, mutect2
- ELOA3 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 44/902 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.147); called by muse, mutect2
- MYBBP1A | c.1262C>G p.S421C | Missense Mutation (SNP) | VAF 28/914 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2
- USP42 | c.2786C>T p.A929V | Missense Mutation (SNP) | VAF 15/255 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- FCHO1 | c.1572G>A p.P524= | Silent (SNP) | VAF 23/381 reads (6%) | called by muse, mutect2
- TMEM40 | c.270G>A p.G90= | Silent (SNP) | VAF 220/496 reads (44%) | called by mutect2, varscan2
- TOP1MT | c.579G>A p.P193= | Silent (SNP) | VAF 48/896 reads (5%) | catalogued as rs368057294; called by muse, mutect2
- DGLUCY | c.*3G>A | 3'UTR (SNP) | VAF 47/316 reads (15%) | catalogued as rs555202642; called by muse, mutect2, varscan2
